Somatic mutation profile of tumor specimen TCGA-OR-A5K1-01A (aliquot TCGA-OR-A5K1-01A-11D-A29I-10) from TCGA case TCGA-OR-A5K1, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 48.2 years (17,596 days).
Specimen TCGA-OR-A5K1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eae6904f-1e01-4cd3-86a9-cbb3f33979b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5K1-10A (Blood Derived Normal), aliquot TCGA-OR-A5K1-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/821dfe32-2709-40ab-aa29-9b7778adec86

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIDO1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 11/315 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs981049274; called by muse, mutect2
- CCP110 | c.811del p.A271Lfs*4 | Frame Shift Del (DEL) | VAF 64/176 reads (36%) | called by mutect2, pindel, varscan2
- DHCR24 | c.387+1G>T p.X129_splice | Splice Site (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- ENO2 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRA1 | c.32T>A p.L11H | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- MGST1 | c.425_428del p.L142Pfs*7 | Frame Shift Del (DEL) | VAF 58/149 reads (39%) | called by mutect2, pindel, varscan2
- RIMS1 | c.4484A>G p.N1495S | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- TRPA1 | c.1432G>A p.G478S | Missense Mutation (SNP) | VAF 195/495 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP26 | c.2488G>C p.V830L | Missense Mutation (SNP) | VAF 31/32 reads (97%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.597); called by muse, mutect2, varscan2
- ZMYND10 | c.1084A>T p.S362C | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2
- ADGRL2 | c.1788A>G p.Q596= | Silent (SNP) | VAF 21/32 reads (66%) | called by muse, mutect2, varscan2
- GPHN | c.1368T>C p.D456= (on ENST00000315266 / NM_001377519.1; = p.D489= on NM_020806.5) | Silent (SNP) | VAF 108/137 reads (79%) | called by muse, mutect2, varscan2
